Surgical pathology report (de-identified scan), TCGA case TCGA-06-2566, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2566-01A (Primary Tumor).

[page 1 of 4]
CLINICAL HISTORY

[REDACTED] woman experiences headaches, and on imaging has left parietal intraparenchymal hemorrhage associated with left parietal mass that has minimal enhancement.

OPERATIVE DIAGNOSES

Left parietal mass

Operation/Specimen: A: Brain, excision biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. B. Brain, left parietal, excision:

1. Malignant astrocytic tumor, with rhabdoid features and leptomeningeal infiltration.

2. MIB-1 proliferation index: 9%.

See Microscopy Description and Comment.

COMMENT

The tumor is a neoplastic proliferation of glial cells that have focal areas with a spindle cell astrocytic phenotype, and extensive areas where the tumor cells have an epithelioid-rhabdoid/pseudorhabdoid morphology. The tumor has prominent mitotic activity and a proliferation index of about 9%. There is focally prominent neovascularization with endothelial hyperplasia, and there is tumor necrosis associated with hemorrhage. The neoplasm is growing extensively in the leptomeninges. There are not mesenchymal, epithelial, or undifferentiated neuroectodermal cell components.

The neoplasm is interpreted as high histological grade astrocytic neoplasm (WHO grade IV) that has a rhabdoid/pseudorhabdoid component. The absence of epithelial, stromal, or primitive neuroectodermal cell components is against the possibility of the tumor being an atypical teratoid/rhabdoid tumor of the cerebrum. Rhabdoid phenotype has been reported with classical glioblastoma (WHO grade IV neoplasm).

[page 2 of 4]
PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

DA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from paraffin tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

[page 3 of 4]
[REDACTED]

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, excision biopsy:

1. Touch prep and smears: Epithelioid, probably fibrillary neoplasm (cell wise suggestive of glial cells). [REDACTED] and results reported to the Physician of Record.

2. Frozen sections: Spindle cell neoplasm, solid, cellular, probably glial, with mitoses. More tissue coming for permanents. [REDACTED] Frozen section performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

"Left parietal brain tumor," received fresh, three fragments, 0.9 cm in aggregate. Firm, glistening, greyish-pink, lobular. In total, A1. Frozen tissue A2.

B. Brain, excision biopsy: "Brain tumor", received fresh, multiple tan-white fragments admixed with blood clot, 2.6 x 1.5 x 0.6 cm in aggregate. All in 2 cassettes.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates heavy gliofibrillogenesis in the spindle cell areas of the neoplasm. Where the tumor is growing in the leptomeninges there is no appreciable gliofibrillogenesis. In the epithelioid/rhabdoid-pseudorhabdoid areas there is rather sparse gliofibrillogenesis.

The tumor cells throughout are strongly immunoreactive with vimentin, and moderately positive with S100. The epithelioid/rhabdoid-pseudorhabdoid cells are strongly positive with vimentin, and only sparsely and focally with GFAP, but without formation of spherical cytoplasmic inclusions. While the spindled neoplastic cells have fine dusting positivity with the mitochondrial antibody, the epithelioid cells are very densely packed by positive granules (oncocytic change). The neoplastic cells are negative with the SMA. The CD 99 is sitive (as may be seen in glioblastomas also).

The neoplastic cells are not reactive with cytokeratin, CK7, EMA, HMB-45, MelanA, NeuN, and synaptophysin. A great majority of tumor cells strongly

[REDACTED]

[page 4 of 4]
over express the p53 protein. With the MIB-1 there is a proliferation index of about 9% in the more active areas.

SPECIAL STAIN: The Snook's reticulum demonstrates dense reticulin network where the neoplasm is invading the leptomeninges. Intraparenchymal tumor growth is prominent in perivascular areas only.

ICD-9(s):
225.0 225.0

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1		
H/E x 1	1		
TPS H/E x 1	1		
H/E x 1	2		

Part B: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
SMA-DA x 1	1		
GFR-slides x 1	1		
SMA-DA x 1	1		
mGFAP-DA x 1	1		
H/E x 1	1		
HMB45-DA x 1	1		
KeratinSu x 1	1		
CK7-DA x 1	1		
MelanA-DA x 1	1		
MGMT-slides x 1	1		
MIB1-DA x 1	1		
CD99-DA x 1	1		
MitoAg x 1	1		
NeuN x 1	1		
P53DO7 x 1	1		
in Immunolab. Thanks.			There may be some blanks
Retic x 1	1		
S100-DA x 1	1		
Synap-DA x 1	1		
Vim-DA x 1	1		
H/E x 1	2		
Retic x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file f3c4fb3c-a3c2-4800-8776-094954ecd40c (TCGA-06-2566.4F4CB14A-6BE7-4240-B220-EDB8FA3C36F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).